Somatic mutation profile of tumor specimen TCGA-CU-A0YO-01A (aliquot TCGA-CU-A0YO-01A-11D-A10S-08) from TCGA case TCGA-CU-A0YO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.4 years (30,817 days).
Specimen TCGA-CU-A0YO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3126596b-11e8-42bb-9c0f-e1d67208eadd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A0YO-10A (Blood Derived Normal), aliquot TCGA-CU-A0YO-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cba441f-d42f-4d66-b647-3d9abbe2bc1f

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Nonsense Mutation 12, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.2806G>A p.V936M | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs752081336, COSV52003930, COSV52013949; called by muse, mutect2, varscan2
- ACHE | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as rs1030385619, COSV53822038; called by muse, mutect2, varscan2
- ASPHD2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1215761224, COSV53218070, COSV53220289; called by muse, mutect2, varscan2
- BPIFB2 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50071732; called by muse, mutect2, varscan2
- C16orf89 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); catalogued as rs780521779, COSV60123985; called by muse, mutect2, varscan2
- CCDC40 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs377613873; called by muse, mutect2, varscan2
- CCKBR | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV58106335; called by muse, mutect2, varscan2
- CDH8 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54852320, COSV54897717; called by muse, mutect2, varscan2
- CIDEB | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs897793055, COSV51868344; called by muse, mutect2, varscan2
- CKMT2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs550283213, COSV54175228; called by muse, mutect2
- COL5A1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV65675828; called by muse, mutect2
- CPT1B | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV56416499, COSV56419304; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CYP27B1 | c.1214A>C p.N405T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV56986855; called by muse, mutect2, varscan2
- DCLK1 | c.1336C>G p.P446A | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55194838, COSV55199549, COSV55214152; called by muse, mutect2, varscan2
- DDX53 | c.1045A>T p.I349F | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60070145; called by muse, mutect2
- DNM1 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57856680; called by muse, mutect2
- FEZ2 | c.645_646del p.R215Sfs*5 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as COSV59907579; called by mutect2, pindel, varscan2
- FUCA2 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs898254349, COSV50021261; called by muse, mutect2, varscan2
- GINS1 | c.331-1G>A p.X111_splice | Splice Site (SNP) | VAF 25/121 reads (21%) | catalogued as COSV52465004, COSV52466856; called by muse, mutect2, varscan2
- GON4L | c.6643G>T p.E2215* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1440150315, COSV99674346; called by muse, mutect2
- GPHB5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV58487321; called by muse, mutect2, varscan2
- HEG1 | c.3148A>G p.K1050E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV60766104; called by muse, mutect2, varscan2
- HRH4 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs760258503, COSV56929856; called by muse, mutect2, varscan2
- INTS9 | c.983T>C p.F328S | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV68436067; called by muse, mutect2
- ITGA8 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs1180380928, COSV65225677; called by muse, mutect2, varscan2
- KIF14 | c.2022G>C p.M674I | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66264395; called by muse, mutect2, varscan2
- KLHDC7B | c.1079G>A p.G360E (on ENST00000395676; = p.G1001E on NM_138433.5) | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67465329; called by muse, mutect2, varscan2
- KLK1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV56828894; called by muse, mutect2, varscan2
- KMT2B | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV52889422, COSV99386062; called by muse, mutect2
- LSS | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs779278365, COSV62703048; called by muse, mutect2, varscan2
- MAP1B | c.4428G>C p.K1476N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV57107401; called by muse, mutect2, varscan2
- MAP4K2 | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV53649305; called by muse, varscan2
- MED12 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV61331442, COSV61356246; called by muse, mutect2, varscan2
- MLF1 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV63032698; called by muse, mutect2, varscan2
- MSLNL | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as rs569040527, COSV53502859; called by muse, mutect2, varscan2
- MYH2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 51/374 reads (14%) | catalogued as COSV55433784; called by muse, mutect2, varscan2
- OGA | c.2504T>C p.F835S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV63383625; called by muse, mutect2
- PAF1 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.011); catalogued as COSV55396526; called by muse, mutect2
- PALM | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52771327; called by muse, mutect2, varscan2
- PCDHGA4 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as rs1201064844, COSV54024061, COSV54046327; called by muse, mutect2, varscan2
- PCDHGB4 | c.2166G>C p.W722C | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV54010647, COSV54046351; called by muse, mutect2, varscan2
- PRR14L | c.5878G>T p.E1960* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | catalogued as COSV100392456; called by muse, mutect2, varscan2
- PTGDR | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60095321; called by muse, mutect2, varscan2
- RFTN2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs780978265, COSV54393875; called by muse, mutect2, varscan2
- RMC1 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52575096; called by muse, mutect2
- RND3 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726208; called by muse, mutect2
- ROBO4 | c.2911C>T p.R971W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774960443, COSV100127801, COSV60624609; called by muse, mutect2, varscan2
- ROS1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199766618, COSV63851597, COSV63858417; called by muse, mutect2, varscan2
- SEMG1 | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as rs751792588, COSV54874867; called by muse, mutect2
- SLC35F2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV56182802; called by muse, mutect2, varscan2
- SMYD1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as rs759065695, COSV70226188; called by muse, mutect2, varscan2
- SUN1 | c.1609G>A p.E537K (on ENST00000405266 / NM_001367651.1; = p.E417K on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV67452257; called by muse, mutect2, varscan2
- SYCE2 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV53368831; called by muse, mutect2, varscan2
- SYNE1 | c.13963A>G p.I4655V (on ENST00000367255 / NM_182961.4; = p.I4584V on NM_033071.3) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55119962; called by muse, mutect2, varscan2
- THEMIS | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV64074816; called by muse, mutect2, varscan2
- TRIO | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100710744, COSV60097968; called by muse, mutect2
- USH1C | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV50039605; called by muse, mutect2, varscan2
- ZNF521 | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV64132505; called by muse, mutect2
- ZNF597 | c.833A>C p.N278T | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV57085239, COSV57085881; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2834C>G p.S945C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL1 | c.3154C>T p.Q1052* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- AL441992.2 | c.1087_1089dup p.R363dup | In Frame Ins (INS) | VAF 6/61 reads (10%) | called by mutect2, pindel
- APOA4 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CD276 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.029); called by muse, mutect2
- CD58 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2
- DDX39B | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- GIGYF1 | c.2498dup p.G834Rfs*35 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- GLO1 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- HLA-A | c.19del p.R7Efs*13 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel, varscan2
- INO80 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- LPAR6 | c.632T>G p.L211* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- MTMR9 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- PHF6 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- RLF | c.575T>G p.I192S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- SF3B3 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 43/278 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.633C>T p.D211= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs1245779397, COSV50996719; called by muse, mutect2
- ECHDC2 | c.588G>C p.L196= (on ENST00000371522 / NM_001198961.2; = p.L165= on NM_018281.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV64302372; called by muse, mutect2, varscan2
- FER | c.2001C>T p.D667= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs574570972, COSV55284746; called by muse, mutect2
- FLRT3 | c.702G>C p.R234= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs1413963482, COSV54063243; called by muse, mutect2, varscan2
- HYDIN | c.12504C>T p.I4168= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV66640974; called by muse, mutect2, varscan2
- INTS13 | c.684G>T p.P228= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV53905874, COSV99677563; called by muse, mutect2, varscan2
- IRX1 | c.1323C>T p.L441= | Silent (SNP) | VAF 13/180 reads (7%) | catalogued as rs370521377, COSV57358222; called by muse, mutect2
- MAGEA1 | c.126C>T p.T42= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV63119371; called by muse, mutect2, varscan2
- MDC1 | c.3273G>A p.E1091= | Silent (SNP) | VAF 59/493 reads (12%) | catalogued as COSV64528215; called by muse, mutect2, varscan2
- MICALL1 | c.2274C>G p.V758= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV53239774, COSV53243092; called by muse, mutect2, varscan2
- PCDHGA1 | c.255C>T p.I85= | Silent (SNP) | VAF 36/336 reads (11%) | catalogued as COSV65300230; called by muse, mutect2
- PDXK | c.756C>T p.L252= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs138572525, COSV99376071; called by muse, mutect2, varscan2
- PRAMEF6 | c.465C>G p.L155= | Silent (SNP) | VAF 54/482 reads (11%) | catalogued as COSV61910613; called by muse, varscan2
- PRR14L | c.6015G>A p.K2005= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV57888523; called by muse, mutect2, varscan2
- RPTOR | c.546G>A p.L182= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1057166744, COSV60819646; called by muse, mutect2, varscan2
- RTL10 | c.333G>A p.P111= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs756600180, COSV60736456, COSV60736594; called by muse, mutect2, varscan2
- SDHD | c.216C>T p.V72= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV54780098; called by muse, mutect2, varscan2
- SLC2A2 | c.1344C>T p.F448= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV58586299; called by muse, mutect2, varscan2
- SORBS2 | c.1704G>T p.R568= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV53017680; called by muse, mutect2
- TAS2R16 | c.171C>T p.F57= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV50799013; called by muse, mutect2, varscan2
- TENT2 | c.1170C>G p.L390= | Silent (SNP) | VAF 66/277 reads (24%) | catalogued as rs371560519; called by muse, mutect2, varscan2
- UMOD | c.1359C>T p.T453= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs144461487; called by muse, mutect2, varscan2
- ZNF337 | c.84G>A p.L28= | Silent (SNP) | VAF 47/365 reads (13%) | catalogued as COSV53323290; called by muse, mutect2, varscan2
- MIR323A | n.50G>A | RNA (SNP) | VAF 16/226 reads (7%) | catalogued as rs762957686; called by muse, mutect2
- OBSCN | c.18662-2343C>T | Intron (SNP) | VAF 9/82 reads (11%) | catalogued as COSV52837370; called by muse, mutect2, varscan2
